Somatic mutation profile of tumor specimen BA3082D (aliquot aq-BA3082D) from BEATAML1.0 case 2822, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.8 years (21,492 days).
Specimen BA3082D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11852256-0f04-4187-8bd2-039aea224b0d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3112D (Solid Tissue Normal), aliquot aq-BA3112D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b7162e2-862e-47c1-8080-058a7c0ba0e1

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Splice Region 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.861G>A p.G287= | Splice Region (SNP) | VAF 23/151 reads (15%) | catalogued as rs540315265; called by muse, mutect2, varscan2
- ATG13 | c.1230+8C>T | Splice Region (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- KDM4C | c.2204A>G p.H735R | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, varscan2
